Somatic mutation profile of tumor specimen TCGA-HE-7129-01A (aliquot TCGA-HE-7129-01A-11D-1961-08) from TCGA case TCGA-HE-7129, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II.
Specimen TCGA-HE-7129-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3dc1879e-9038-4825-a9bb-88e3ccbfd697.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HE-7129-10A (Blood Derived Normal), aliquot TCGA-HE-7129-10A-01D-1962-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b429505-a327-4662-949a-7e4357aecd48

The open-access MAF lists 42 somatic variants for this specimen: 28 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 13, Frame Shift Del 2, Splice Site 2, Nonsense Mutation 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs751717780, COSV67017824; called by muse, mutect2, varscan2
- ANKZF1 | c.1485G>T p.W495C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV55477550, COSV99850242; called by mutect2, varscan2
- BAZ1A | c.3000T>C p.V1000= | Splice Region (SNP) | VAF 23/42 reads (55%) | catalogued as COSV62411105; called by muse, mutect2, varscan2
- BLMH | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs778865567, COSV55586170; called by muse, mutect2, varscan2
- CCN4 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as COSV51533753; called by muse, mutect2, varscan2
- CCP110 | c.1879T>A p.F627I | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV66817366; called by mutect2, varscan2
- CILK1 | c.922C>G p.L308V | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV63155148; called by muse, mutect2, varscan2
- CNOT1 | c.3244A>G p.T1082A | Missense Mutation (SNP) | VAF 265/418 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.253); catalogued as COSV55319494; called by muse, mutect2, varscan2
- COL27A1 | c.3956C>G p.P1319R | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV61924893, COSV61928466; called by muse, mutect2, varscan2
- DSCAML1 | c.2320G>A p.D774N (on ENST00000321322; = p.D714N on NM_020693.4) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV58394629; called by muse, varscan2
- EMD | c.451del p.X151_splice | Splice Site (DEL) | VAF 35/51 reads (69%) | catalogued as COSV63962500; called by mutect2, pindel, varscan2
- ESR2 | c.485G>C p.G162A | Missense Mutation (SNP) | VAF 133/306 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50834637; called by muse, mutect2, varscan2
- GP1BA | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs779512159, COSV56700067; called by muse, mutect2
- HSF5 | c.1135G>C p.V379L | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as COSV60417929; called by muse, mutect2, varscan2
- ITGB3 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 62/96 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV71384595; called by muse, mutect2, varscan2
- KY | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 93/131 reads (71%) | catalogued as COSV71018026; called by muse, mutect2, varscan2
- LIMA1 | c.1616G>C p.G539A | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV57966782; called by muse, mutect2, varscan2
- OR8I2 | c.689C>G p.A230G | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV56166679, COSV56168996; called by muse, mutect2
- PCDH15 | c.4986A>T p.K1662N | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious, low confidence (0.01); catalogued as COSV64711275; called by muse, mutect2, varscan2
- PLCL2 | c.945G>T p.L315F (on ENST00000615277 / NM_001144382.2; = p.L189F on NM_015184.5) | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.822); catalogued as COSV67623501; called by muse, mutect2, varscan2
- PRDM2 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52450711, COSV52454211; called by muse, mutect2, varscan2
- SRSF7 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as COSV57447740; called by muse, mutect2, varscan2
- TEX14 | c.2911C>G p.P971A (on ENST00000240361 / NM_001201457.2; = p.P965A on NM_031272.5) | Missense Mutation (SNP) | VAF 66/239 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV53621067; called by muse, mutect2, varscan2
- TNRC6A | c.4739G>A p.S1580N | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as rs761975967, COSV59367248; called by muse, mutect2, varscan2
- ARID4A | c.2018del p.S673* | Frame Shift Del (DEL) | VAF 48/127 reads (38%) | called by mutect2, pindel, varscan2
- CRACDL | c.2550_2551del p.R851Dfs*5 | Frame Shift Del (DEL) | VAF 38/99 reads (38%) | called by mutect2, pindel, varscan2
- PDK4 | c.567_575del p.S189_G192delinsR | In Frame Del (DEL) | VAF 109/212 reads (51%) | called by mutect2, pindel, varscan2
- SLC6A4 | c.1819-17_1828del p.X607_splice | Splice Site (DEL) | VAF 18/82 reads (22%) | called by mutect2, pindel
- AP3M1 | c.48A>G p.L16= | Silent (SNP) | VAF 42/81 reads (52%) | catalogued as COSV62331845; called by muse, mutect2, varscan2
- ASB10 | c.828G>C p.L276= (on ENST00000420175 / NM_001142459.2; = p.L261= on NM_080871.4) | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV51998433; called by muse, mutect2, varscan2
- CCM2 | c.780C>T p.T260= | Silent (SNP) | VAF 37/155 reads (24%) | catalogued as CD135542, COSV51849747; called by muse, mutect2, varscan2
- CYB561 | c.606C>T p.N202= | Silent (SNP) | VAF 28/43 reads (65%) | catalogued as rs772551964, COSV62539998; called by muse, varscan2
- HNRNPAB | c.351G>A p.L117= | Silent (SNP) | VAF 88/170 reads (52%) | catalogued as rs201431713, COSV57425155; called by mutect2, varscan2
- LAMP1 | c.237C>T p.S79= | Silent (SNP) | VAF 59/104 reads (57%) | catalogued as COSV60212180; called by muse, mutect2, varscan2
- MED24 | c.1917G>A p.S639= | Silent (SNP) | VAF 38/176 reads (22%) | catalogued as rs572516214, COSV62419748; called by mutect2, varscan2
- MUC2 | c.1542G>A p.V514= | Silent (SNP) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- RBFOX2 | c.282T>C p.P94= (on ENST00000438146 / NM_001349995.2; = p.P24= on NM_014309.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/123 reads (44%) | catalogued as COSV53266273; called by muse, mutect2, varscan2
- RIN2 | c.864C>T p.S288= (on ENST00000255006 / NM_001242581.1; = p.S239= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV54790840; called by muse, mutect2, varscan2
- SRSF7 | c.15G>T p.G5= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV57447746; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3999G>A p.G1333= | Silent (SNP) | VAF 85/211 reads (40%) | catalogued as COSV64101720; called by muse, mutect2, varscan2
- ZKSCAN1 | c.72A>G p.V24= | Silent (SNP) | VAF 42/168 reads (25%) | catalogued as COSV60874746; called by muse, mutect2, varscan2
- DCHS2 | n.1074A>C | RNA (SNP) | VAF 51/97 reads (53%) | catalogued as COSV59732208; called by muse, mutect2, varscan2
